TCGA case TCGA-AZ-4615 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bf69a4ce-ec7e-4752-a86d-dcc80e3c9a57

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 84.6 years (30,908 days); Year of diagnosis: 2009; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: RX; Days to last follow up: 1,002 days (2.7 years).
   Pathology details: Circumferential resection margin: 50; Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 18; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 264 days; Number of cycles: 8; Route of administration: Oral.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Liver; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 86.5 years (31,596 days); Days to diagnosis: 688 days (1.9 years); Prior treatment: Yes.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 688 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to recurrence: 688 days (1.9 years).
- Days to follow up: 1,002 days (2.7 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 506.

Molecular and laboratory tests
- CEA: 2.1 ng/mL.
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 170 cm; BMI: 29.1.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AZ-4615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.2.
  Slide TCGA-AZ-4615-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-AZ-4615-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10.
- Sample TCGA-AZ-4615-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AZ-4615-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; CEA level pretreatment: 2.1; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: Yes; KRAS mutation found: No.
- Drug treatment: Pharmaceutical therapy drug name: Xeloda.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,002 days; disease-specific survival: no event (censored), 1,002 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 688 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AZ-4615-01A-01D-1406-01): tumor purity 0.65, ploidy 2.04, whole-genome doublings 0.
